MMRF case MMRF_1802 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/a90e9b42-dc3c-4916-ab66-6c967971cfa0

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 63 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 63.8 years (23,301 days); ISS stage: I; Days to last known disease status: 973 days (2.7 years); Days to last follow up: 973 days (2.7 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 54 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 57 days.
   Treatment given: Therapeutic agents: Cyclophosphamide + Dexamethasone + Other; Regimen or line of therapy: First line of therapy; Days to treatment start: 85 days; Days to treatment end: 85 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 111 days; Days to treatment end: 111 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 111 days; Days to treatment end: 111 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 232 days; Days to treatment end: 232 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 234 days; Days to treatment end: 234 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 235 days; Days to treatment end: 235 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 236 days; Days to treatment end: 236 days.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 973.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -9 (ECOG 1): M Protein 2.46 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 11.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 251 mg/dL; Immunoglobulin G 36.9 g/L; Immunoglobulin A 0.1 g/L; Immunoglobulin M 0.12 g/L; Beta 2 Microglobulin 2.8 µg/mL; Lactate Dehydrogenase 2.43 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 3.9 ×10⁹/L; Platelets 312 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.33 mmol/L; Albumin 36 g/L; Total Protein 9.5 g/dL.
- Day 85 (ECOG 1): M Protein 0.35 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.498 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.89 mg/dL; Immunoglobulin G 7.32 g/L; Immunoglobulin A 0.28 g/L; Immunoglobulin M 0.2 g/L; Beta 2 Microglobulin 1.55 µg/mL; Lactate Dehydrogenase 2.37 µkat/L; Hemoglobin 8.8 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 3.6 ×10⁹/L; Platelets 211 ×10⁹/L; Creatinine 78.7 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.28 mmol/L; Albumin 45 g/L; Total Protein 6.3 g/dL; Glucose 7.04 mmol/L.
- Day 169 (ECOG 1): M Protein 0.16 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.1 mg/dL; Immunoglobulin G 5.4 g/L; Immunoglobulin A 0.32 g/L; Immunoglobulin M 0.05 g/L; Beta 2 Microglobulin 1.52 µg/mL; Hemoglobin 8.31 mmol/L; Leukocytes 6.7 ×10⁹/L; Absolute Neutrophil 4.7 ×10⁹/L; Platelets 203 ×10⁹/L.
- Day 267 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.1 mg/dL; Beta 2 Microglobulin 1.39 µg/mL; Lactate Dehydrogenase 8.52 µkat/L; Hemoglobin 8.18 mmol/L; Leukocytes 14.9 ×10⁹/L; Absolute Neutrophil 14 ×10⁹/L; Platelets 221 ×10⁹/L; Creatinine 75.1 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.33 mmol/L; Albumin 39 g/L; Total Protein 5.9 g/dL; Glucose 8.58 mmol/L.
- Day 421 (ECOG 1): Hemoglobin 8.68 mmol/L; Leukocytes 6.5 ×10⁹/L; Absolute Neutrophil 4.6 ×10⁹/L; Platelets 178 ×10⁹/L.
- Day 516 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 0.825 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.13 mg/dL; Immunoglobulin G 6.72 g/L; Immunoglobulin A 0.24 g/L; Immunoglobulin M 0.62 g/L; Beta 2 Microglobulin 1.93 µg/mL; Lactate Dehydrogenase 3.33 µkat/L; Hemoglobin 8.25 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 3.5 ×10⁹/L; Platelets 172 ×10⁹/L; Creatinine 83.1 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.25 mmol/L; Albumin 45 g/L; Total Protein 6.3 g/dL; Glucose 5.78 mmol/L.
- Day 608 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.04 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.538 mg/dL; Immunoglobulin G 6.34 g/L; Immunoglobulin A 0.26 g/L; Immunoglobulin M 0.49 g/L; Lactate Dehydrogenase 2.53 µkat/L; Hemoglobin 9.36 mmol/L; Leukocytes 8.5 ×10⁹/L; Absolute Neutrophil 6.4 ×10⁹/L; Platelets 172 ×10⁹/L; Creatinine 81.3 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.18 mmol/L; Albumin 44 g/L; Total Protein 6.1 g/dL; Glucose 5.12 mmol/L.
- Day 790 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 0.949 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.778 mg/dL; Immunoglobulin G 5.55 g/L; Immunoglobulin A 0.41 g/L; Lactate Dehydrogenase 2.82 µkat/L; Hemoglobin 9.18 mmol/L; Leukocytes 8.4 ×10⁹/L; Absolute Neutrophil 6 ×10⁹/L; Platelets 200 ×10⁹/L; Creatinine 89.3 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.33 mmol/L; Albumin 46 g/L; Total Protein 6.5 g/dL; Glucose 5.06 mmol/L.
- Day 874 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.951 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.96 mg/dL; Immunoglobulin G 5.65 g/L; Immunoglobulin A 0.55 g/L; Immunoglobulin M 0.7 g/L; Lactate Dehydrogenase 2.57 µkat/L; Hemoglobin 9.05 mmol/L; Leukocytes 7.7 ×10⁹/L; Absolute Neutrophil 5.4 ×10⁹/L; Platelets 157 ×10⁹/L; Creatinine 83.1 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.3 mmol/L; Albumin 45 g/L; Total Protein 6.3 g/dL; Glucose 7.21 mmol/L.
- Day 972 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.16 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.974 mg/dL; Immunoglobulin G 6.05 g/L; Immunoglobulin A 0.79 g/L; Immunoglobulin M 0.72 g/L; Lactate Dehydrogenase 2.93 µkat/L; Hemoglobin 9.42 mmol/L; Leukocytes 7.1 ×10⁹/L; Absolute Neutrophil 4.5 ×10⁹/L; Platelets 178 ×10⁹/L; Creatinine 87.5 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.25 mmol/L; Albumin 46 g/L; Total Protein 6.5 g/dL; Glucose 4.02 mmol/L.

Other clinical attributes
- Day -9: Weight: 73 kg; Height: 157 cm.

Family history
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Kidney Cancer.
- Relative with cancer history: yes; Relationship type: Sibling.
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Prostate Cancer; Relationship sex at birth: male.

Biospecimens (2 samples)
- Sample MMRF_1802_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -9 days.
- Sample MMRF_1802_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -9 days.
